RC case RC-B65F — RC-PTCL: Refractory Cancers (RC) - Peripheral T-Cell Lymphoma (PTCL)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Mature T- and NK-Cell Lymphomas; Primary site: Liver and intrahepatic bile ducts. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/f532059f-63aa-40ad-9b00-d9b8ece3aef9

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Year of birth: 1984; Vital status: Alive.

Diagnoses (2)
1. Hepatosplenic T-cell lymphoma (the primary disease): ICD-O-3 morphology code: 9716/3; ICD-10 code: C84; Tissue or organ of origin: Liver; Site of resection or biopsy: Blood; Classification of tumor: primary; Age at diagnosis: 27.3 years (9,988 days); Year of diagnosis: 2011; Method of diagnosis: Incisional Biopsy; Ann Arbor B symptoms: Yes; Prior malignancy: yes; Synchronous malignancy: No; Prior treatment: No; Ann arbor b symptoms described array: Fever / Night Sweats; Ann Arbor extranodal involvement: Yes; International Prognostic Index (IPI): High-Intermediate Risk; Sites of involvement: Bone marrow / Peripheral blood.
   Pathology details: Bone marrow malignant cells: Yes; Timepoint category: Initial Diagnosis.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cytarabine + Etoposide + Ifosfamide; Initial disease status: Initial Diagnosis; Regimen or line of therapy: IVAC; Days to treatment start: 8 days; Days to treatment end: 67 days; Number of cycles: 4; Treatment outcome: Complete Response; Reason treatment ended: Course of Therapy Completed; Timepoint category: First Treatment; Treatment effect indicator: Yes.
   Treatment given: Treatment type: Stem Cell Transplantation, Allogeneic; Days to treatment start: 97 days; Treatment outcome: Complete Response; Treatment effect indicator: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Treatment intent type: Adjuvant; Treatment outcome: Complete Response; Timepoint category: Postoperative.
   Treatment given: Treatment type: Radiation Therapy, NOS; Treatment intent type: Adjuvant; Treatment outcome: Complete Response; Timepoint category: Postoperative.
   Recorded as not given: Organ Transplantation; Stem Cell Transplantation, Autologous; Stem Cell Transplantation, NOS.
2. Prior malignancy of the skin (histology not recorded by GDC).
   Treatment given: Treatment type: Surgery, NOS; Treatment anatomic sites: Other.
   Recorded as not given: Pharmaceutical Therapy, NOS; Radiation Therapy, NOS.

Follow-up (4 entries)
- Day 0 (initial diagnosis): Karnofsky performance status: 80.
- Days to follow up: 77 days; Disease response: Tumor Free.
- Day 3,483 (end of treatment course 1): Disease response: Tumor Free.
- Days to follow up: 3,875 days (10.6 years); Disease response: Tumor Free.

Molecular and laboratory tests
- Lactate Dehydrogenase 663 U/L [Blood test normal range upper: 250].
- Epstein-Barr Virus: Negative [Test analyte type: DNA].

Other clinical attributes
- Timepoint category: Prior to Diagnosis; Immunosuppressive treatment type: Prednisone.
- Timepoint category: Prior to Diagnosis; Immunosuppressive treatment type: Anti-TNF Therapy.
- Timepoint category: Prior to Diagnosis; Immunosuppressive treatment type: Other.
- Timepoint category: Initial Diagnosis; Weight: 67.9 kg; Height: 183 cm; BMI: 20.3.
- Timepoint category: Prior to Diagnosis; Comorbidities: Crohn's Disease.
- Timepoint category: Prior to Diagnosis; Risk factors: Skin Rash.
- Timepoint category: Prior to Diagnosis; Immunosuppressive treatment type: Azathioprine.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker.

Family history
- Relative with cancer history: no.

Biospecimens (2 samples)
- Sample RC-B65F-NB1-A: Tissue type: Normal; Specimen type: Granulocytes; Preservation method: Frozen.
- Sample RC-B65F-TBP1-A: Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Whole Blood; Preservation method: Frozen.
